Somatic mutation profile of tumor specimen TCGA-RW-A685-01A (aliquot TCGA-RW-A685-01A-11D-A35D-08) from TCGA case TCGA-RW-A685, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 70.6 years (25,790 days).
Specimen TCGA-RW-A685-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56371448-70c5-4509-aeb8-693c015600a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A685-10A (Blood Derived Normal), aliquot TCGA-RW-A685-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931d20a5-eaf7-4347-9560-8dcf3c758fbc

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP2 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1441502007; called by muse, mutect2, varscan2
- NF1 | c.2350T>A p.W784R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM020464; called by muse, mutect2, varscan2
- POU6F2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV68870284; called by muse, mutect2, varscan2
- ACADM | c.417T>A p.D139E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MSANTD4 | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCDHGC3 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- RORC | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL9 | c.3342C>T p.L1114= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- FN1 | c.3282C>T p.Y1094= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs991952311; called by muse, mutect2, varscan2
- XPOT | c.1188A>G p.E396= | Silent (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- BIRC5 | c.222-635C>A | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
